Gene-level copy-number profile of tumor specimen TCGA-75-5147-01A from TCGA case TCGA-75-5147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-5147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2b9a389f-e9ba-479e-a101-ad0612fdec4d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-5147-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b51c3f0-f17e-4711-9032-1ec36491f8d8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,465; copy number 2: 15,741; copy number 3: 26,466; copy number 4: 11,145; copy number 5: 346; copy number 6: 2,189; copy number 7: 1,616; copy number 8: 141; copy number 9: 652; copy number 11: 53; copy number 12: 2; copy number 13: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-5147-01A-01D-1624-01): tumor purity 0.4, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,467 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 9–13 (broad region; genes not listed).
- chr5:63,022,919–63,571,617, 3 genes, copy number 7: AC113420.1, AC025445.1, AC008558.1.
- chr5:146,084,313–181,342,213, 691 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr11:9,019,476–14,872,044, 115 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:15,481,808–17,207,983, 23 genes, copy number 8 (within-gene range 3–8): AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58, PLEKHA7, RN7SKP90, AC116533.1, OR7E14P, RPS13, SNORD14A, SNORD14B, PIK3C2A, RNU6-593P, AC126389.1.
- chr11:17,788,048–18,042,426, 3 genes, copy number 8 (within-gene range 3–8): SERGEF, AC055860.1, TPH1.
- chr18:47,390–23,662,911, 436 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–40,465,764, 486 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
